Somatic mutation profile of tumor specimen MMRF_1721_1_BM_CD138pos (aliquot MMRF_1721_1_BM_CD138pos_T1_KBS5U_L04788) from MMRF case MMRF_1721, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.5 years (21,017 days).
Specimen MMRF_1721_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a294ec5-96a1-4c3e-83ab-0856420b675b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1721_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1721_1_PB_Whole_C3_KBS5U_L04801; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86fc57d3-b26a-46de-8bb1-5bca0a97c42c

The open-access MAF lists 97 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 27, Silent 10, Intron 6, 3'Flank 4, 5'UTR 4, RNA 3, Nonsense Mutation 2, 5'Flank 2, Splice Region 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTAGE1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs755487694, COSV66942800; called by muse, mutect2, varscan2
- CTNND1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1486500759, COSV62385314; called by muse, mutect2, varscan2
- IGHJ4 | c.34A>T p.T12S | Missense Mutation (SNP) | VAF 55/62 reads (89%) | PolyPhen benign (0.015); catalogued as rs374291610; called by muse, mutect2, varscan2
- IGHV2-70 | c.214A>C p.I72L | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs374012300; called by muse, varscan2
- IGHV2-70 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770314362; called by muse, varscan2
- IGLV3-1 | c.47-2A>C p.X16_splice | Splice Site (SNP) | VAF 36/76 reads (47%) | catalogued as rs181922188; called by muse, varscan2
- IGLV3-1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs548457166; called by muse, varscan2
- LINGO1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 98/198 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs373336312; called by muse, mutect2, varscan2
- LY75-CD302 | c.5519C>T p.S1840F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV52028075; called by muse, mutect2, varscan2
- NF1 | c.3496G>A p.G1166S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as CS147221, COSV62227948; called by muse, mutect2, varscan2
- PYGB | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs754264308; called by muse, mutect2, varscan2
- TNK1 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs778650950; called by muse, mutect2, varscan2
- TNRC18 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV68087678, COSV68087973; called by muse, mutect2, varscan2
- ZFPM2 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780534224, COSV101023145, COSV65874081; called by muse, mutect2, varscan2
- DAAM1 | c.2732A>G p.E911G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DNAJC6 | c.2363G>A p.G788D | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM168A | c.413G>C p.R138T (on ENST00000064778 / NM_001286050.2; = p.R129T on NM_015159.3) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- FBXL20 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GABRG3 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- ICE1 | c.6326T>A p.L2109Q | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IKZF3 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, varscan2
- ISYNA1 | c.1472+8C>T | Splice Region (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2
- ISYNA1 | c.1472+6C>T | Splice Region (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2
- MUC17 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 182/426 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.8907_8909delinsAA p.T2970Kfs*20 | Frame Shift Del (DEL) | VAF 95/474 reads (20%) | called by pindel, varscan2*
- MYH15 | c.4474G>C p.E1492Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NDFIP2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PALMD | c.1408A>T p.S470C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PCDH10 | c.2075G>A p.G692E | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PCDHGB5 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRKD2 | c.1142T>A p.L381Q | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAMP1 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RNF32 | c.669dup p.F224Ifs*3 | Frame Shift Ins (INS) | VAF 40/84 reads (48%) | called by mutect2, varscan2
- SHLD2 | c.2480T>C p.V827A | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); called by mutect2, varscan2
- SI | c.2400A>T p.Q800H | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLIT2 | c.3170C>T p.P1057L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TKTL2 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- TPR | c.5628T>G p.S1876R | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- TRIM50 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBTB8B | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF573 | c.382T>C p.Y128H (on ENST00000536220 / NM_001172692.1; = p.Y70H on NM_152360.3) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANHX | c.87C>T p.C29= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV69293358; called by muse, mutect2, varscan2
- FANCF | c.1020A>G p.E340= | Silent (SNP) | VAF 162/310 reads (52%) | called by muse, mutect2, varscan2
- HTR1A | c.732A>G p.A244= | Silent (SNP) | VAF 86/191 reads (45%) | catalogued as COSV60503022; called by muse, mutect2, varscan2
- IL18R1 | c.870C>T p.S290= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV52126232; called by muse, mutect2, varscan2
- LPCAT3 | c.621C>T p.H207= | Silent (SNP) | VAF 26/31 reads (84%) | called by muse, mutect2, varscan2
- OR4C12 | c.9G>A p.K3= | Silent (SNP) | VAF 9/209 reads (4%) | catalogued as COSV58860183; called by muse, mutect2
- PXDN | c.3558G>A p.E1186= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as rs1193855391; called by muse, mutect2, varscan2
- RNF133 | c.795T>C p.P265= | Silent (SNP) | VAF 104/223 reads (47%) | called by muse, mutect2, varscan2
- STAT5B | c.324C>T p.C108= | Silent (SNP) | VAF 38/106 reads (36%) | called by muse, varscan2
- THBS3 | c.2721C>A p.I907= | Silent (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- ADAM12 | c.*390T>C | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- AFF1 | c.*10A>G | 3'UTR (SNP) | VAF 120/248 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.3185-37C>A | Intron (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- ARHGEF16 | c.*461G>T | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- ATG2B | chr14:96276425 G>C | 3'Flank (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- BARX2 | c.*657C>T | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- BCL7A | chr12:122021648 G>A | 5'Flank (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- CACNA1I | c.*2832C>T | 3'UTR (SNP) | VAF 73/141 reads (52%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113453510 A>C | 3'Flank (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CCNYL1 | c.*2137G>A | 3'UTR (SNP) | VAF 99/212 reads (47%) | called by muse, mutect2, varscan2
- CLCN1 | c.774+466G>T | Intron (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- CPEB4 | c.-566T>C | 5'UTR (SNP) | VAF 73/163 reads (45%) | called by muse, mutect2, varscan2
- CREB5 | c.*5854C>G | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- CUL2 | c.*1089T>A | 3'UTR (SNP) | VAF 16/36 reads (44%) | catalogued as rs1040006901, COSV66079864; called by muse, varscan2
- DTX1 | c.-71G>A | 5'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- EBF2 | c.*2672C>T | 3'UTR (SNP) | VAF 90/192 reads (47%) | called by muse, mutect2, varscan2
- EML2 | c.*46G>A | 3'UTR (SNP) | VAF 39/86 reads (45%) | catalogued as rs781748828; called by muse, mutect2, varscan2
- FAM8A1 | c.*2570A>G | 3'UTR (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- FANCD2P2 | n.353T>C | RNA (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- FGFRL1 | c.*1036G>T | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- GBP4 | c.*1650T>A | 3'UTR (SNP) | VAF 85/192 reads (44%) | called by muse, mutect2, varscan2
- GRIN2A | c.*7828A>G | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- INSC | c.*730C>T | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- LINC02872 | n.1359G>T | RNA (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- LINC02872 | n.1360G>T | RNA (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- LOX | c.*723T>C | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- MIR30C2 | chr6:71376926 C>G | 3'Flank (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- OTUD3 | c.*2397_*2398dup | 3'UTR (INS) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- PARP15 | c.*577A>G | 3'UTR (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- PDXDC1 | c.22-9410G>A | Intron (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- PRPF38B | c.559-1122T>G | Intron (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+4243T>A | Intron (SNP) | VAF 64/102 reads (63%) | called by muse, mutect2, varscan2
- RAB1B | chr11:66268634 G>T | 5'Flank (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- RWDD2B | c.*1779A>T | 3'UTR (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- SAP30L | c.-444G>A | 5'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- SERF2 | c.7+97C>T | Intron (SNP) | VAF 129/259 reads (50%) | catalogued as rs992486089; called by muse, mutect2, varscan2
- SLC5A10 | c.*813G>A | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- SRGAP1 | c.*3349G>A | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- TBRG1 | c.-167C>A | 5'UTR (SNP) | VAF 44/68 reads (65%) | catalogued as rs931984548; called by muse, mutect2, varscan2
- TMEM192 | c.*948A>G | 3'UTR (SNP) | VAF 22/46 reads (48%) | catalogued as rs1202560772; called by muse, mutect2, varscan2
- TMPRSS2 | c.*675C>G | 3'UTR (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- TRAF6 | chr11:36488209 A>T | 3'Flank (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- WDR72 | c.*510G>T | 3'UTR (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ZFAND5 | c.*4498A>G | 3'UTR (SNP) | VAF 43/76 reads (57%) | called by muse, mutect2, varscan2
- ZFX | c.*1951T>C | 3'UTR (SNP) | VAF 23/24 reads (96%) | called by muse, mutect2, varscan2
- ZHX3 | c.*2683C>A | 3'UTR (SNP) | VAF 69/124 reads (56%) | called by muse, mutect2, varscan2
